Surgical pathology report (de-identified scan), TCGA case TCGA-RW-A686, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site Michigan University, specimen TCGA-RW-A686-06A (Metastatic).

[page 1 of 2]
PREVIOUS DIAGNOSIS INQUIRY

REPORT DATE:
NAME:
BIRTHDATE:

PAGE #: 1
SEX: M
ADM DATE:

ACCESSION:

OPER DATE:

REQ DOC:

PROCEDURE: SPHS

VERIFIED BY:

Patient with pheochromocytoma - left. Operative Procedure/Tissue Submitted:
En bloc resection, left adrenal pheochromocytoma.

PROCEDURE: SPGD

VERIFIED BY:

1. "En bloc resection, left kidney and left adrenal pheochromocytoma."
Received in formalin in a large container is a 530 gram, 16 x 11 x 7 cm en bloc resection of kidney and adrenal glands with perirenal fat. There is an irregular nodular mass partially covered by perirenal fat at the medial upper and intrapolar region of the kidney and overlying the hilum (abutting the hilar vasculature). The nodular mass is encapsulated. Mass is inked green and the specimen is bivalved revealing a mahogany colored neoplasm (10.9 x 6.8 x 4.2 cm) arising from the adrenal medulla abutting the seminal vessels and the adipose of the renal hilum, but maintaining a tissue plane and not invading. The mass has a lobular architecture and abuts the upper half of the medial aspect of the kidney, and again maintaining a tissue plane without invasion. The remainder of the kidney is unremarkable. A few nodules initially mistaken for possible lymph nodes are identified; however, upon further inspection these nodules directly extended to the main mass and are, therefore, considered to be part of the tumor. No lymph nodes are identified in the perinephric fat. Photographs are taken for reference.

1A. Ureter and vascular margins.

1B & 1C. Bisected section of tumor adjacent to renal hilum.

1D & 1E. Bisected section of tumor adjacent to renal hilum.

1F - 1H. Additional sections of tumor with a tumor adjacent to possible normal adrenal cortex in 1H.

1I. Uninvolved renal cortex from inferior pole of kidney.

1J. Tumor.

1K. Possible residual adrenal gland.

2. "Periaortic lymph node #1." Received in formalin in a small container is a 2.1 x 1.4 x 1.1 cm lymph node serially sectioned revealing pale pink cross sections with a rim of pale orange. Entirely submitted in cassettes 2A and 2B.

3. "Periaortic lymph node #2." Received in formalin in a small container is a 2.9 x 2.1 x 1.8 cm lymph node. This specimen is serially sectioned revealing pink cross sections with scattered areas of hemorrhage and a rim of orange tissue. Likely grossly positive.

3A. Representative cross section.

ICD-0-3

Pheochromocytoma, malignant 8700/3

Site: ^{CSCE} Adrenal gland NOS C74.9
^{path} Medulla of adrenal gland C74.1
QW 12/13/13

[page 2 of 2]
PREVIOUS DIAGNOSIS INQUIRY

REPORT DATE:
NAME:
BIRTHDATE:

PAGE #: 2
SEX: M
ADM DATE:

ACCESSION: OPER DATE: REQ DOC:

PROCEDURE: SPDX VERIFIED BY:

1. Left kidney and adrenal gland, resection: Pheochromocytoma (10.9 cm) involving perinephric and renal hilar adipose tissue. Vascular invasion present. Margins negative. Unremarkable left kidney.
2. Periaortic lymph node #1, excision: Metastatic pheochromocytoma to one lymph node (1/1).
3. Periaortic lymph node #2, excision: Metastatic pheochromocytoma to one lymph node (1/1).

I, the signing staff pathologist, have personally examined and interpreted the slides from this case.

Code:

** END OF PREVIOUS DIAGNOSIS INQUIRY **

Source: NCI Genomic Data Commons file 622f67db-5068-4e86-9b5e-4f2cd34e5e82 (TCGA-RW-A686.AB1B615A-EBA8-4004-A508-0622B1FB29D5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).